Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A8HB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A8HB-01A (Primary Tumor).

[page 1 of 6]
Collected:

Ordered by:

DIAGNOSIS:

ANTERIOR EXENTERATION WITH ILEO CONDUIT AND GASTROSTOMY TUBE PLACEMENT:

RIGHT MEDIAL URETER (A):
FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT LATERAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT DISTAL URETER (C):

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (D):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBE AND BLADDER (E):

BLADDER:

- INVASIVE PAPILLARY UROTHELIAL (TRANSITIONAL CELL) CARCINOMA (5.5 X 3.5 X 1.5 CM), HIGH GRADE 3-4/4, INFILTRATING INTO THE DEEP MUSCULARIS PROPRIA, BUT NOT THROUGH IT
- MULTIFOCAL HIGH GRADE DYSPLASIA WITH CARCINOMA IN SITU (FLAT LESION) ON ANTERIOR, POSTERIOR AND LEFT LATERAL URINARY BLADDER WALL
- ALL SURGICAL MARGINS, FREE OF TUMOR

PERIVESICAL LYMPH NODES:

- NO TUMOR IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

UTERUS:

- CERVIX, CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA
- ENDOMETRIUM, PROLIFERATIVE ENDOMETRIUM
- MYOMETRIUM, NO SIGNIFICANT LESION
- SEROSAL SURFACE, NO SIGNIFICANT LESION
- BILATERAL FALLOPIAN TUBES, NO SIGNIFICANT LESION
- BILATERAL OVARIES, NORMAL PHYSIOLOGIC CHANGES

LEFT PARA AORTIC LYMPH NODES (F):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT PARACAVAL LYMPH NODES (G):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT COMMON ILIAC LYMPH NODES (I):

ICD-O-3

Carcinoma, papillary
transitional 8/30/13

Site 4 Bladder NOS
C67.9

gnd 1/20/14

[page 2 of 6]
Collected:

Ordered By:

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT LYMPH NODE OF CLOQUET (J):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT EXTERNAL ILIAC LYMPH NODES (K):

- FIBROFATTY TISSUE
- NO LYMPHOID TISSUE OR TUMOR IDENTIFIED (0/0)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT LYMPH NODE OF CLOQUET (N):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- NO TUMOR IDENTIFIED IN 12 LYMPH NODES EXAMINED (0/12)

RIGHT PRESACRAL LYMPH NODES (P):

- FIBROFATTY CONNECTIVE TISSUE
- NO LYMPHOID TISSUE OR TUMOR IDENTIFIED (0/0)

PRESACRAL LYMPH NODES (Q):

- FIBROFATTY CONNECTIVE TISSUE
- NO LYMPHOID TISSUE OR TUMOR IDENTIFIED

LEFT PRESACRAL LYMPH NODES (R):

- FIBROFATTY CONNECTIVE TISSUE
- NO LYMPHOID TISSUE IDENTIFIED

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT MEDIAL PROXIMAL MARGIN OF URETER (T):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT INTERNAL PROXIMAL URETERAL MARGIN (U):

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

ISOLATED LYMPH NODE (V):

- ENTIRE LYMPH NODE REPLACED BY FATTY TISSUE
- NO LYMPHOID TISSUE OR TUMOR IDENTIFIED (0/0)

LYMPH NODE SUMMARY: NO TUMOR IDENTIFIED IN 45 LYMPH NODES EXAMINED (0/45)

PATHOLOGIC TNM STAGE: pT2bN0Mx

Electronically signed by
Verified:

[page 3 of 6]
Collected:

Ordered by:

COMMENT:

notified of the results on

SPECIMEN SOURCE:

A: "Right M F/S"
B: "Right L F/S"
C: "RT. distal ureter"
D: "LT. distal ureter F/S"
E: "Uterus, cervix, ovaries, bladder"
F: "Lt. para aortic L.N."
G: "Right para caval L.N."
H: "Rt. common iliac L.N."
I: "Lt. common iliac L.N."
J: "Rt. L.N. of cloquet"
K: "Rt external iliac L.N."
L: "Rt. obturator / hypogastric L.N."
M: "Lt. external iliac L.N."
N: "Lt. L.N. of cloquet"
O: "Lt. obturator / hypogastric L.N."
P: "Rt. pre-sciatic L.N."
Q: "Pre sacral L.N."
R: "Lt. pre sciatic L.N."
S: "Lt proximal ureter"
T: "Right medial proximal margin of ureter"
U: "Right internal proximal ureteral margin"
V: "Isolated lymph node"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "Right M F/S". It consists of a portion of ureter measuring 0.4 cm in length and 0.4 cm in diameter. The specimen is entirely submitted for frozen section in cassette in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Right L F/S". It consists of a portion of ureter measuring 0.4 cm in length and 0.5 cm in diameter. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen specimen is received fresh from the O.R. and labelled "RT. distal ureter". It consists of a portion of ureter measuring 0.4 cm in length and 0.6 cm in diameter. The specimen is entirely submitted in one cassette for permanent section.

D: The specimen is received fresh from the O.R. and labelled "LT. distal ureter F/S". It consists of a portion of ureter measuring 0.4 cm in length and 0.6 cm in diameter. The specimen is entirely submitted for frozen section in cassette DFS.

E: The specimen is received fresh from the O.R. and labeled "Uterus, cervix, ovaries, bladder". It consists of urinary bladder, uterus, cervix, and bilateral ovaries and fallopian tubes measuring overall 33 x 16 x 4 cm. The attached peritoneum measures 33 x 12 x 0.1 cm, which is smooth and glistening. The perivesical resection margin is inked black. The urinary bladder is opened anteriorly to reveal fungating papillary lesion in the upper posterior urinary bladder wall. The mass measures 5.5 x 3.5 x 1.5 cm. The remaining mucosa of the urinary bladder is red-tan in color. The right ureter measures 8 cm in length and

[page 4 of 6]
Collected

Ordered by

0.8 cm in circumference, and the left ureter measures 7 cm in length and 0.8 cm in circumference. Both ureters are grossly unremarkable. Bilaterally, the ureterovesical junction is 2.5 cm inferior to the tumor. The uterus measures 8.5 x 5 x 3.5 cm and is covered by an unremarkable serosa. The cervix measures 2.5 cm in length and 2.5 cm in diameter. The external cervix is smooth and glistening. The uterus is opened to reveal unremarkable endocervical cavity and endocervical canal. The endocervical canal measures 3 cm in length and 0.5 cm in circumference. The endometrial cavity measures 3.5 x 3 cm. The endometrium measures 0.1 cm and the myometrium measures 1 to 1.5 cm in thickness. The right fallopian tube measures 8.5 cm in length and 0.4 cm in diameter. The right ovary measures 3 x 2 x 1 cm. The left fallopian tube measures 9 cm in length and 0.5 cm in diameter. The left ovary measures 3 x 1.8 x 0.7 cm. The bilateral adnexa are grossly unremarkable. A piece of vaginal mucosa is also identified measuring 8 x 7 x 0.1 cm and is uninvolved by tumor grossly. Representative sections are submitted in a total of 34 cassettes.

F: The specimen is received in formalin and labelled "Lt. para aortic L.N.". It consists of a piece of tan soft tissue measuring 3 x 0.8 x 0.4 cm. The specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labelled "Right para caval L.N.". It consists of a piece of tan soft tissue measuring 3 x 0.6 x 0.2 cm. The specimen is entirely submitted in two cassettes.

H: The specimen is received in formalin and labelled "Rt. common iliac L.N.". It consists of a piece of tan soft tissue measuring 3 x 1.5 x 0.2 cm. The specimen is entirely submitted in three cassettes.

I: The specimen is received in formalin and labelled "Lt. common iliac L.N.". It consists of a piece of tan soft tissue measuring 2.8 x 1.2 x 0.4 cm. The specimen is entirely submitted in three cassettes.

J: The specimen is received in formalin and labelled "Rt. L.N. of cloquet". It consists of a piece of tan soft tissue measuring 1.2 x 0.6 x 0.4 cm. The specimen is entirely submitted in one cassette.

K: The specimen is received in formalin and labelled "Rt external iliac L.N.". It consists of multiple tan-yellow fibroadipose tissue fragments measuring 3 x 1 x 0.4 cm in aggregate. The specimen is entirely submitted in four cassettes.

L: The specimen is received in formalin and labelled "Rt. obturator / hypogastric L.N.". It consists of multiple tan soft tissue fragments measuring 4 x 1 x 0.4 cm in aggregate. The specimen is entirely submitted in five cassettes.

M: The specimen is received in formalin and labelled "Lt. external iliac L.N.". It consists of multiple tan soft tissue fragments measuring 3 x 1.5 x 0.4 cm in aggregate. The specimen is entirely submitted in five cassettes.

N: The specimen is received in formalin and labelled "Lt. L.N. of cloquet". It consists of a piece of tan soft tissue measuring 1.8 x 1.2 x 0.4 cm. The specimen is entirely submitted in one cassette.

O: The specimen is received in formalin and labelled "Lt. obturator / hypogastric L.N.". It consists of multiple tan soft tissue fragments measuring 3 x 2 x 0.8 cm in aggregate. The specimen is entirely submitted in four cassettes.

P: The specimen is received in formalin and labelled "Rt. pre-sciatic L.N.". It consists of right presciatic lymph node. It consists of multiple tan soft adipose tissue fragments measuring 1.5 x 0.4 x 0.3 cm. The specimen is entirely submitted in one cassette.

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected: _____

Ordered by: _____

Q: The specimen is received in formalin and labelled "Pre sacral L.N.". It consists of a piece of tan soft tissue measuring 4 x 1.5 x 0.2 cm. The specimen is entirely submitted in three cassettes.

R: The specimen is received in formalin and labelled "Lt. pre sciatic L.N.". It consists of multiple tan soft tissue fragments measuring 0.8 x 0.6 x 0.2 cm in aggregate. The specimen is entirely submitted in one cassette.

S: The specimen is received in formalin and labelled "Lt proximal ureter". It consists of a portion of ureter measuring 0.4 cm in length and 0.4 cm in diameter. The specimen is entirely submitted in one cassette.

T: The specimen is received in formalin and labelled "Right medial proximal margin of ureter". It consists of a portion of ureter measuring 0.6 cm in length and 0.4 cm in diameter. The specimen is entirely submitted in one cassette.

U: The specimen is received in formalin and labelled "Right internal proximal ureteral margin". It consists of a portion of ureter measuring 0.3 cm in length and 0.4 cm in diameter. The specimen is entirely submitted in one cassette.

V: The specimen is received in formalin and labelled "Isolated lymph node". It consists of a lymph node measuring 1.8 x 0.8 x 0.6 cm. The lymph node is bisected and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right M F/S
BFS: frozen section, right L F/S
C: right distal ureter - all embedded
DFS: frozen section, left distal ureter F/S
E1: urethral margin
E2: anterior bladder wall
E3: right lateral bladder wall
E4: right ureterovesical junction
E5: dome
E6: posterior urinary bladder wall
E7: trigone to urethra
E8: left lateral urinary bladder wall
E9: left ureterovesical junction
E10,11: full thickness tumor to vaginal mucosa
E12-15: tumor
E16: vagina
E17: anterior cervix
E18: posterior cervix
E19: anterior endomyometrium
E20: posterior endomyometrium
E21: right adnexa
E22: left adnexa
E23-26: right perivesical fat for lymph node
E27-30: left perivesical adipose tissue for lymph node
E31-34: additional sections of the tumor
F1-3: left para-aortic lymph node - all embedded
G1,2: right paracaval lymph node - all embedded
H1-3: right common iliac lymph node - all embedded
I1-3: left common iliac lymph node - all embedded
J: right lymph node of Cloquet - all embedded
K1-4: right external iliac lymph node - all embedded.
L1-5: right obturator/hypogastric lymph node - all embedded
M1-5: left external iliac lymph node - all embedded
N: left lymph node of Cloquet - all embedded

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Q1-4: left obturator / hypogastric lymph node - all embedded
P: right presciatic lymph node - all embedded
Q1-3: presacral lymph node - all embedded
R: left presciatic lymph node - all embedded
S: left proximal ureter - all embedded
T: right medial proximal margin of ureter - all embedded
U: right internal proximal ureteral margin - all embedded
V: isolated lymph node - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right medial ureter:
- negative

BFS: Right lateral ureter :
- negative

DFS: Left distal ureter:
- negative

INTRAOPERATIVE GROSS CONSULTATION

E: BLADDER

- TUMOR PRESENT WITH GROSSLY FREE MARGINS

MICROSCOPIC EXAMINATION:

A-D: See final microscopic-diagnosis.

E: Sections show an invasive papillary urothelial carcinoma infiltrating into the deep layer of the muscularis propria, but not through it (E34). Multi foci of high grade urothelial carcinoma in situ are identified (E2, 6, 8). There are suggestive of lymphovascular invasions noted. All the surgical margins are free of malignancy. No metastatic urothelial carcinoma identified in five perivesical lymph nodes (0/5) examined.

Sections of the uterus show chronic cervicitis with squamous metaplasia, weakly proliferative endometrium. Bilateral ovaries display physiologic changes and bilateral fallopian tubes are unremarkable.

G-V: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 0ce2e6f8-7827-4f37-9635-fa446627cbc8 (TCGA-XF-A8HB.AEEB69FF-8CC6-4E22-AD71-A55B11595314.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).